Somatic mutation profile of tumor specimen 0DJA09 from CCDI case PBBWUH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.7 years (3,538 days).
Specimen 0DJA09: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 516b4738-d707-4820-8a82-cebc82cc078a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJ9ZX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d9901c9-05d9-4bcb-b643-4c904c42aebf

The open-access MAF lists 36 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 6, Intron 3, 3'UTR 2, Frame Shift Ins 2, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOX2 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 81/385 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201115263, COSV57147767; called by muse, mutect2, varscan2
- ADCY10 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 208/423 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1375557111; called by muse, mutect2, varscan2
- FXYD5 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 74/502 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779297539, COSV61569465; called by muse, mutect2, varscan2
- H1-7 | c.680C>A p.P227Q | Missense Mutation (SNP) | VAF 93/457 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV58602128; called by muse, mutect2, varscan2
- LAIR1 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 52/384 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.437); catalogued as rs1425720525, COSV57307167; called by muse, mutect2
- LMOD3 | c.637del p.I213Yfs*4 | Frame Shift Del (DEL) | VAF 124/615 reads (20%) | catalogued as rs773282804; called by mutect2, pindel, varscan2
- MARCHF1 | c.547G>A p.E183K (on ENST00000274056; = p.E166K on NM_017923.4) | Missense Mutation (SNP) | VAF 66/457 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760767827, COSV56811044; called by muse, mutect2, varscan2
- MYOM1 | c.3507C>A p.F1169L | Missense Mutation (SNP) | VAF 70/530 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV55291051; called by muse, mutect2, varscan2
- OGFOD1 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 108/531 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs370136242; called by muse, mutect2, varscan2
- OR10Q1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 74/330 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as rs746612596, COSV100372159, COSV57471918; called by muse, mutect2, varscan2
- SF3B1 | c.1988C>T p.T663I | Missense Mutation (SNP) | VAF 65/338 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239341681, COSV59206194; called by muse, mutect2, varscan2
- TEX101 | c.263C>A p.A88D (on ENST00000598265 / NM_001130011.3; = p.A106D on NM_031451.4) | Missense Mutation (SNP) | VAF 83/471 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); catalogued as COSV53662045; called by mutect2, varscan2
- ANKRD31 | c.1415T>A p.M472K | Missense Mutation (SNP) | VAF 71/421 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- APOE | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 85/542 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); called by muse, mutect2
- CACNA2D4 | c.1370C>A p.S457* | Nonsense Mutation (SNP) | VAF 137/701 reads (20%) | called by muse, mutect2, varscan2
- CCDC27 | c.392A>C p.H131P | Missense Mutation (SNP) | VAF 205/456 reads (45%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CKM | c.1120G>T p.D374Y | Missense Mutation (SNP) | VAF 111/714 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CYP3A7 | c.433-1G>T p.X145_splice | Splice Site (SNP) | VAF 50/356 reads (14%) | called by muse, mutect2, varscan2
- MUC12 | c.11114C>A p.S3705Y (on ENST00000379442; = p.S3562Y on NM_001164462.1) | Missense Mutation (SNP) | VAF 35/284 reads (12%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- NEU4 | c.542T>C p.V181A (on ENST00000391969 / NM_001167602.3; = p.V193A on NM_080741.4) | Missense Mutation (SNP) | VAF 125/612 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- PHKA2 | c.85G>C p.V29L | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- PRSS41 | c.385C>A p.L129M | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- PTPRZ1 | c.5641dup p.S1881Ffs*21 | Frame Shift Ins (INS) | VAF 68/544 reads (13%) | called by mutect2, pindel, varscan2
- RYR1 | c.6567dup p.V2190Sfs*63 | Frame Shift Ins (INS) | VAF 48/283 reads (17%) | called by mutect2, pindel, varscan2
- UTY | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- CLDN17 | c.516T>C p.A172= | Silent (SNP) | VAF 111/459 reads (24%) | called by muse, mutect2, varscan2
- GSTA3 | c.627T>C p.D209= | Silent (SNP) | VAF 159/1091 reads (15%) | catalogued as rs1018712048; called by muse, mutect2, varscan2
- KIR3DL2 | c.651C>T p.I217= | Silent (SNP) | VAF 72/510 reads (14%) | called by muse, mutect2, varscan2
- LRRC10 | c.339C>G p.L113= | Silent (SNP) | VAF 74/331 reads (22%) | called by muse, mutect2, varscan2
- NUGGC | c.957C>T p.S319= | Silent (SNP) | VAF 80/244 reads (33%) | catalogued as rs1281870278; called by muse, mutect2, varscan2
- SHROOM2 | c.4560C>T p.D1520= | Silent (SNP) | VAF 106/245 reads (43%) | catalogued as rs183701518, COSV66606815; called by muse, mutect2, varscan2
- CARD14 | c.1594+33G>A | Intron (SNP) | VAF 50/520 reads (10%) | called by muse, mutect2
- CRIP2 | c.197-70G>A | Intron (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- FAM53A | c.883-2743C>T | Intron (SNP) | VAF 74/476 reads (16%) | catalogued as rs539062104; called by muse, mutect2, varscan2
- FCRL4 | c.*17G>A | 3'UTR (SNP) | VAF 47/236 reads (20%) | catalogued as rs755685686, COSV99619684; called by muse, mutect2, varscan2
- XCL1 | c.*11C>A | 3'UTR (SNP) | VAF 18/450 reads (4%) | called by muse, mutect2
